Surgical pathology report (de-identified scan), TCGA case TCGA-09-2049, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site UCSF, specimen TCGA-09-2049-01D (Primary Tumor).

[page 1 of 3]
FINAL PATHOLOGIC DIAGNOSIS

A. Left ovary, fallopian tube, salpingo-oophorectomy:

1. Ovary with papillary serous carcinoma, high grade; see comment.
2. Fallopian tube with no significant pathologic abnormality.

B. Right ovary, fallopian tube, salpingo-oophorectomy:

1. Ovary with serous cystadenoma.
2. Fallopian tube with papillary serous carcinoma obstructing lumen and hydrosalpinx.

C. Omentum, partial omentectomy: Metastatic high grade papillary serous carcinoma.

D. Uterus, cervix, abdominal hysterectomy:

-Cervix: High grade serous papillary carcinoma of superior cervix.

-Endometrium:

1. High grade serous papillary carcinoma involving polyp.
2. Mildly proliferative glands.

-Myometrium:

1. Adenomyosis.
2. Leiomyoma.

-Serosa: No significant pathologic abnormality.

E. Colon, biopsy:

1. Metastatic high grade papillary serous adenocarcinoma, infiltrating peri-colic fat and portion of intestinal wall.
2. Colonic mucosa with no significant pathologic abnormality.

Page 1 of 4

F. Appendix, appendectomy: Appendix with focal intraluminal calcification. No tumor seen.

COMMENT:

Ovarian Tumor Synoptic Comment

Type of tumor: Papillary serous carcinoma.

Grade of tumor: high grade, delineated as follows: papillary architecture 2 points, nuclear pleomorphism 2 points, mitoses 3 points for a sum of 8 points = high grade.

Site of tumor: Left ovary, (also right fallopian tube, endometrial polyp, superior cervix, perirectal soft tissue, omentum).

Location of tumor: intracystic and surface of ovary.

Condition of capsule: not encapsulated.

Cut surface: solid and cystic.

Necrosis: moderate.

Lymphatic/vascular invasion: not identified.

Sites of metastasis in pelvis: Left fallopian tube, cervix, endometrial polyp (see comments below); diameter of largest pelvic metastasis = 1.7 cm, right fallopian tube.

Pelvic lymph nodes: None sampled.

Sites of metastasis in abdomen: omentum and peri-rectal soft tissue; maximum diameter of largest abdominal metastasis = 1.4 cm, omentum.

Para-aortic lymph nodes: None sampled.

Peritoneal cytology: positive, metastatic papillary adenocarcinoma; (

Other abnormalities: endometrial polyp, adenomyosis.

FIGO stage: IIIC.

[page 2 of 3]
[REDACTED]

TNM stage: pT3c Nx M0.

Additional comments: We favor this to be a primary serous carcinoma of the left ovary with peritoneal spread to the right adnexa, and intracavitary spread to the endometrial polyp and superior cervix. The possibility of a primary uterine carcinoma with spread to the ovary seems unlikely given the extensive involvement of the left ovary with tumor. Multiple synchronous primary serous carcinomas cannot be excluded yet also seems less likely. [REDACTED] has reviewed the slides and concurs.

Specimen(s) Received

A: Left Ovary [REDACTED]
B: Right Ovary
C: Omentum
D: Uterus
E: Colon tissue fragments
F: Appendix, incidental
G: Ovary Blocks- [REDACTED]

Intraoperative Diagnosis

FS1 (A) Left ovary, salpingo-oophorectomy: Papillary serous carcinoma.

FS2 (B) (Gross evaluation only) Hydrosalpinx. Specimen not frozen, but left intact for sampling of
Page 2 of 4

nodular near cystic area. [REDACTED]

FS3 (C) (Gross evaluation only) Omentum: Grossly involved by tumor. [REDACTED]

Clinical History

The patient is a [REDACTED] [REDACTED] with a history of severe glandular atypia on prior endocervical curettage

[REDACTED] who undergoes total abdominal hysterectomy and bilateral salpingo-oophorectomy, omentectomy, biopsy of colonic implant and appendectomy.

Gross Description

The specimen is received in seven parts, each labeled with the patient's name and unit number.

Part A, labeled "left ovary", consists of a grossly distorted ovary weighing 243 grams and measuring 10 x 7

x 9 cm. There are multiple papillated masses on the surface. A portion of fallopian tube is identified which measures 6 cm in length and 1 cm in greatest diameter. Serial sectioning reveals that the nearly the entire

ovarian mass consists of tan-pink, soft, friable, papillary structure. Cassette A1 contains a frozen section remnant. Representative sections of the mass are submitted in cassettes A2-A6.

Part B, labeled "right ovary", consists of an ovary with a portion of fallopian tube weighing 83.5 grams and

measuring 7 x 6 x 4.8 cm. The fallopian tube measures 7 cm in length and 2 cm in greatest diameter at the

portion of hydrosalpinx. A large cyst is associated with the ovary measuring 6.5 cm in greatest diameter and containing clear serous fluid. The external surfaces are inked in black. The internal surface of the cyst cavity is smooth. A 1.3 cm nodular area beneath the cyst wall is visible in the region of the adherence of the

fimbriae to the ovary. Sections through this region reveals a mass which is contiguous with the internal surface of the fallopian tube obstructing the distal orifice. This mass measures 1.7 cm in greatest diameter.

A section of this area is submitted in cassette B1. Two irregularly-shaped white fibrous-appearing areas are

also beneath the internal cyst wall; each measuring <1.5 cm in greatest diameter. Representative sections of this fibrous area as well as a section of normal-appearing fallopian tube are submitted in cassette B2.

Part C, labeled "omentum", consists of a section of yellow, fatty omental tissue measuring 30 x 15 x 4 cm. The central portion is firm and indurated, with a tan-white mass, which in some regions has a papillated

[page 3 of 3]
[REDACTED]

border. This central area of caking measures 14 cm in greatest diameter. Representative sections are submitted in cassettes C1-C3.

Part D, labeled "uterus", consists of a 113 gram, pink-tan uterus which measures 9.5 cm superior to inferior, 6 cm laterally, and 4.5 cm in anterior posterior dimension. The cervical os measures 1 cm and is fish mouth. The cut surfaces are inked in black. The endometrial surface is smooth, yellow-tan and focally hemorrhagic. Two polyps emanate from the anterior left endometrium; one measuring 2.5 cm in greatest diameter. Small cystic spaces are present within the myometrium which measures 2 cm in greatest dimension. The spaces measure 0.2 cm in greatest dimension. Representative sections are submitted as follows:

Cassette D1: Anterior cervix,

Cassette D2: Posterior cervix.

Cassette D3: Anterior endometrium with cystic space and superior polyp.

Cassette D4: Anterior endomyometrium.

Cassette D5: Anterior lower uterine segment with polyp.

Cassette D6: Posterior endometrium.

Cassette D7: Section of lower posterior endomyometrium.

Cassette D8: Section of superior endomyometrium with serosa.

Cassette D9: Section of superior posterior subserosal nodule.

Cassettes D10-14: Serial ascending sections of anterior superior cervix through lower uterine segment.

Cassettes D15-18: Serial ascending sections of left anterior endometrium with base of polyp.

Cassette D19: Anterior endometrial polyp.

Part E, received in formalin, labeled "tissue from colon", consists of multiple irregularly-shaped, yellow-tan masses of fatty, firm tissue measuring 5 x 3 x 1.2 cm in aggregate. One specimen appears to contain cystic

Page 3 of 4

structures associated with the firm, white nodule. Representative sections are submitted in cassette E1.

Part F, received in formalin, labeled "appendix", consists of a segment of appendix measuring 2 in length and 0.7 cm in diameter, with an adjacent 2 cm fatty mesentery. The external surfaces are inked black. Representative sections are submitted in cassette F1.

Part G, is received as 11, tan research cassettes, each containing tissue for the [REDACTED]

The tan cassettes are labeled in sequential order as [REDACTED] These tan cassettes are subsequently submitted as cassettes G1-G11.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED]

Source: NCI Genomic Data Commons file a7ff3452-471e-40d6-a2dd-b856d4f17af7 (TCGA-09-2049.17564604-CE57-4087-887A-F97A5B280B26.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).